Surgical pathology report (de-identified scan), TCGA case TCGA-UB-A7MA, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UCSF, specimen TCGA-UB-A7MA-01A (Primary Tumor).

[page 1 of 8]
[REDACTED]

Results

Result Information

Status (Last updated Date/Time)

Accession #

Result Impression

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Sex: Female

Soc. Sec. #: [REDACTED]

Accession #: [REDACTED]

Visit #: [REDACTED]

Service Date:

Received:

Location:

Client:

ICD-O-3

Hepatocellular carcinoma
8180/3

Site Liver
C22.0

9/26/13

FINAL PATHOLOGIC DIAGNOSIS

A. Bile duct margin, biopsy: No tumor.

B. Liver, left lobe, partial hepatectomy: Mixed hepatocellular/cholangiocarcinoma, extending to margin and invading large vessels; see comment.

C. Hepatic artery lymph node, excision: No carcinoma in one lymph node (0/1).

D. Anterior common hepatic artery lymph node, excision: No carcinoma in one lymph node (0/1).

E. Portacaval lymph node, excision: No carcinoma in one lymph node (0/1).

COMMENT:

Liver Tumor, Including Intrahepatic Bile Duct, Synoptic Comment

- Tumor type: Mixed hepatocellular/cholangiocarcinoma.
- Histologic grade: Moderately differentiated.
- Tumor size (maximum diameter of largest lesion): 12.1 cm.
- Tumor necrosis: <30%.
- [REDACTED]

[page 2 of 8]
[REDACTED]

- Multifocality (more than one tumor separated by nontumorous liver parenchyma): Present.

- Estimated total tumor diameter of all HCC foci: >12 cm.
- Vascular invasion: Present in both large and small vessels (B2, B3, B8).
- Hepatic capsule: Tumor abuts capsule.
- Local extension of tumor: Confined to liver.
- Hepatic surgical margins: Positive (slide B3); see comment.
- Bile duct margin (for cholangiocarcinoma): Negative.
- Non-neoplastic liver: No significant pathologic abnormality.
- Lymph node status: Negative.
- Negative; total number of nodes examined: 3.
- AJCC Stage: pT3bN0.

Immunoperoxidase and special stains were performed to confirm the diagnosis and show the following staining pattern in tumor cells:

- Chromogranin: Negative.
- Synaptophysin: Negative.
- Arginase: Patchy positive, negative in some areas showing glandular differentiation.
- CK19: Strong and diffusely positive.
- Mucicarmine: Negative.
- MIB1: Briskly positive, with nuclear staining up to 40-50% of cells.

Overall, the histopathology and immunohistochemical profile support a diagnosis of mixed hepatocellular/cholangiocarcinoma. Histologic sections show divergent differentiation with some larger cells showing eosinophilic cytoplasm or fatty differentiation. These cells are arranged in a trabecular architecture. Both the morphology as well as strong positive staining for arginase supports hepatoid differentiation in these areas. In other areas, discrete glands within sclerotic stroma are seen. Luminal necrosis is seen within glands. A subset of these areas of glandular differentiation lack arginase staining. This finding, along with the presence of necrosis provide evidence for a component of cholangiocarcinoma. Of note, a mucicarmine stain is negative, indicating a lack of mucin; however, this does not preclude a diagnosis of cholangiocarcinoma. MIB1 staining shows a proliferative index of up to 40-50%, suggesting a highly proliferative malignancy. Negative staining for synaptophysin and chromogranin argues against neuroendocrine differentiation.

Sections at the periphery of the main mass show multiple smaller nodules, some of which are only apparent microscopically. One of these small nodules is found at the margin (slide B3). It is possible that this nodule may represent venous invasion.

have reviewed portions of this case
and concur with the diagnosis.

Specimen(s) Received
A: Bile duct left (ink marks distal margin) FS
B: Left lobe liver
C: Hepatic artery lymph node
D: Anterior common hepatic artery lymph node
E: Portacaval lymph node

Intraoperative Diagnosis

[REDACTED]

[page 3 of 8]
[REDACTED]

FS1 (A) Bile duct, left, biopsy: Benign bile duct, almost entirely denuded. Dr. agrees.

Clinical History

The patient is a -year-old woman with a left-sided liver mass. According to she presented with left upper quadrant in and a CT at that time revealed a left-sided liver mass and no risk factors for hepatocellular carcinoma. A core biopsy revealed hepatocellular carcinoma with focal glandular differentiation CK19-positive, AFP-negative, arginase-positive). She is additionally noted to have a history of splenectomy for hereditary spherocytosis and is status post cholecystectomy in for cholecystitis, which work-up revealed papillary stenosis with a narrowing of the common bile duct.

Gross Description

The case is received in five parts, labeled with the patient's name and medical record number.

Part A is received fresh and additionally labeled "2 bile duct left ink marks distal margin frozen," and consists of a single fragment of red-tan soft tissue (0.7 x 0.3 x 0.1 cm) marked by a circle of black ink on the one end. The entire specimen is frozen for frozen section diagnosis 1, and subsequently submitted in cassette A1.

Part B is received fresh and additionally labeled "left lobe liver orientation P," and consists of a partial hepatectomy (739.5 gm fixed; 14.5 cm from right to left x 16.5 cm from anterior to posterior x 8.3 cm from superior to inferior) without attached gallbladder. The specimen is previously disrupted at the capsule with a section taken by the surgeon for banking prior to receipt in Pathology.

GROSS ABNORMALITIES: There is a white-tan, firm, multinodular well-circumscribed mass (12.1 cm from right to left x 8 cm from superior to inferior x 14 cm from anterior to posterior) that extends to the capsule, which is distorted and contracted by the mass. The mass is noted 0.5 cm from the resection margin (slice 6). There is no grossly evident necrosis within the mass. Additionally, scattered smaller white-tan nodules are seen adjacent to, but apparently distinct from the mass. The liver parenchyma is otherwise red-brown, firm, and unremarkable. No gallbladder is present. No lymph nodes are identified.

ORIENTED BY: Anatomic landmarks; hepatic ligament.

INKING:

- Liver capsule overlying mass: Inferior in blue and superior in green.
- Resection margin: Black.

POTENTIAL STUDIES: Normal and tumor are taken for tissue banking.

CASSETTES: Representative sections are submitted:

B1-B2: Mass, approach to margin, and vessels, slice 6.

B3: Mass, approach to margin, and vessels, slice 7.

B4-B9: Representative sections of mass, including mass adjacent to capsule.

B10: Uninvolved liver.

Part C is received fresh and additionally labeled "hepatic artery lymph node," and consists of a single, curved/irregular, soft, rubbery red-tan lymph node (2.5 x 1 x 0.7 cm). The specimen is bisected and

[REDACTED]

[page 4 of 8]
[REDACTED]

entirely submitted in cassettes C1-C2.

Part D is received fresh and additionally labeled "anterior common hepatic artery lymph node," and consists of a single, roughly ovoid, soft, rubbery pink-tan lymph node (2.8 x 1.2 x 0.6 cm). The specimen is bisected and entirely submitted in cassettes D1-D2.

Part E is received fresh and additionally labeled "porta caval lymph node," and consists of a single, irregular, soft, rubbery pink-tan lymph node (2.8 x 1.6 x 1 cm). The specimen is trisected and entirely submitted in cassettes C1-C3.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Electronically signed out

Pathology PDF Report

Show images for Surgical Pathology

Authorizing

Name: _____

Phone: _____

Signed by

Signed

Date/Time

Phone

Pager

Result History

This is NOT a Requisition. Requisition hyperlink below.

Surgical Pathology (Order

Pathology and Cytology

Authorizing: _____

Department: _____

Images

Show images for Surgical Pathology

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Release Information

Released On

Released By

Order Details

[REDACTED]

[page 5 of 8]
Frequency
Once

Duration
1 occurrence

Priority
Routine

Order Class
Normal

Lab Collection and Receipt Information

Collect Date

Collect Time

Collected By

Lab Receipt Date

Lab Receipt Time

Collection Information

Resulting Agency

Order Provider Info

Ordering User

Authorizing Provider

Billing Provider

Office
phone

Pager/beeper

E-mail

--

--

--

Electronically Signed By

Electronically Authorized By

Electronically Ordered By

Order Status for: SURGICAL PATHOLOGY

Parent Status: Completed

Child Orders

Order Requisition

[page 6 of 8]
[REDACTED]

Results

Surgical Pathology

Result Information

Status (Last updated Date/Time)

Accession #
[REDACTED]

Result Impression

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Sex: Female

Soc. Sec. #: [REDACTED]

Accession #: [REDACTED]

Visit #: [REDACTED]

Location:

FINAL PATHOLOGIC DIAGNOSIS

Histochemical staining for iron and interpretation on

Background liver with 2+ positive staining (0-4+).

COMMENT:

A histochemical stain for iron was performed on block B10 of
This shows 2+ staining of hepatocytes and kupfer cells (scale 0-4+).

Gross Description

block B10 is selected for histochemical staining.

Clinical History

The patient is a -year-old woman with mixed
hepatocellular/cholangiocarcinoma and a history of hereditary
spherocytosis. An iron stain was requested by

Diagnosis based on gross and microscopic examinations. Final diagnosis
made by attending pathologist following review of all pathology slides.
The attending pathologist has reviewed all dictations and preliminary
interpretations performed by any resident involved in the case and

[REDACTED]

[page 7 of 8]
[REDACTED]

performed all necessary edits before signing the final report.

Pathology PDF Report

Show images for Surgical Pathology

Authorizing Provider Information

Name:

Phone:

Signed by

Signed

Phone

Pager

Result History

This is NOT a Requisition. Requisition hyperlink below.

Surgical Pathology (Order

Pathology and Cytology

Department:

By:

Show images for Surgical Pathology

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

Release Information

Released On

Released By

Order Details

Frequency
Once

Duration
1 occurrence

Priority
Routine

Order Class
Normal

Lab Collection and Receipt Information

Collect Date

Collect Time

Collected By

Lab Receipt Date

Lab Receipt Time

Collection Information

Resulting Agency

Order Provider Info

[REDACTED]

[page 8 of 8]
Office

E-mail

Ordering User
Authorizing Provider

Billing Provider

--
--
--

Electronically Signed By:

Electronically Authorized By

Electronically Ordered By

Order Status for: SURGICAL PATHOLOGY

Parent Status: Completed

Child Orders

(This order does not yet have any children)

Order Requisition

Source: NCI Genomic Data Commons file 1ec7af1b-dd30-4d7b-b93b-2c9a037730e8 (TCGA-UB-A7MA.82349CD5-39AA-42F8-80A1-B438B2300D09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).